Somatic mutation profile of tumor specimen TCGA-AA-3675-01A (aliquot TCGA-AA-3675-01A-02W-0900-09) from TCGA case TCGA-AA-3675, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage II; Age at diagnosis: 84.3 years (30,801 days).
Specimen TCGA-AA-3675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 512a2688-c5fa-46f7-80b9-bcaebe622fe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3675-10A (Blood Derived Normal), aliquot TCGA-AA-3675-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/380ec44d-3049-4f57-8c8e-5c62ed3022d8

The open-access MAF lists 106 somatic variants for this specimen: 71 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 31, Nonsense Mutation 7, RNA 3, Frame Shift Del 3, In Frame Del 2, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 77/98 reads (79%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.8713C>T p.R2905* | Nonsense Mutation (SNP) | VAF 76/92 reads (83%) | catalogued as rs128627256, CM950347, COSV58922146; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 91/295 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 35/106 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 52/151 reads (34%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BMP3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as COSV99261976; called by muse, mutect2, varscan2
- CA6 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.752); catalogued as COSV101077664; called by muse, mutect2
- CACNA1D | c.3955C>T p.R1319C (on ENST00000350061 / NM_001128840.3; = p.R1339C on NM_000720.4) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193002808, COSV55448799; called by muse, mutect2, varscan2
- CALD1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773676427, COSV62647273; called by muse, mutect2, varscan2
- CC2D2A | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs145678228; called by muse, mutect2, varscan2
- CCDC110 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100294135; called by muse, mutect2, varscan2
- CD109 | c.2044A>T p.S682C | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99754423; called by muse, mutect2, varscan2
- CLCA1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 126/326 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as COSV52328639, COSV99322747; called by muse, mutect2, varscan2
- COLGALT1 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as COSV99395249; called by muse, mutect2, varscan2
- CUL5 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV101263667; called by muse, mutect2, varscan2
- DHX30 | c.127T>G p.S43A (on ENST00000445061 / NM_138615.3; = p.S4A on NM_014966.3) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.661); catalogued as COSV100820107; called by muse, mutect2, varscan2
- ERI3 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100952241; called by muse, mutect2, varscan2
- EVA1C | c.633C>T p.F211= | Splice Region (SNP) | VAF 27/65 reads (42%) | catalogued as rs761406200, COSV100291563; called by muse, mutect2, varscan2
- GRIK4 | c.1644G>T p.W548C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101483727; called by muse, mutect2, varscan2
- HPCA | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs138767632; called by muse, mutect2, varscan2
- HRG | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs756432163, COSV99215011; called by muse, mutect2, varscan2
- KAT14 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100890108; called by muse, mutect2, varscan2
- KCNB2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV73050758; called by muse, mutect2, varscan2
- KIAA0100 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs775633494, COSV66494291; called by muse, mutect2, varscan2
- LARP4 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53323789; called by muse, mutect2, varscan2
- LGR6 | c.1492G>T p.E498* (on ENST00000367278 / NM_001017403.1; = p.E446* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 81/124 reads (65%) | catalogued as COSV99707731; called by muse, mutect2, varscan2
- MARCHF7 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1290081640, COSV52029105; called by muse, mutect2
- MGAM | c.3287T>G p.I1096S | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1431849178, COSV101527722; called by muse, mutect2, varscan2
- MUC16 | c.11833C>A p.H3945N | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as rs1182432079, COSV101201302; called by muse, mutect2, varscan2
- MYH6 | c.3778G>T p.E1260* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100676937; called by muse, mutect2, varscan2
- MYO1E | c.551C>G p.P184R | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99896483; called by muse, mutect2, varscan2
- NBAS | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs370943197; called by muse, mutect2, varscan2
- OBSCN | c.4559G>A p.R1520Q | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.489); catalogued as rs377740226; called by muse, mutect2, varscan2
- OPN1SW | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs1424127387, COSV99975882; called by muse, mutect2, varscan2
- OR56A4 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100417676, COSV58111352; called by muse, mutect2, varscan2
- OSBPL6 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99507420; called by muse, mutect2, varscan2
- PCDHA12 | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.284); catalogued as rs782415331, COSV56516545; called by muse, mutect2, varscan2
- PCDHGA11 | c.1895C>A p.A632E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV99545600; called by muse, mutect2, varscan2
- PPARGC1A | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 57/155 reads (37%) | catalogued as COSV53524732, COSV99338522; called by muse, mutect2, varscan2
- PRKAG2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.9); catalogued as rs41317142, COSV55232567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.10250C>T p.A3417V | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58056116; called by muse, mutect2, varscan2
- PRMT3 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as COSV100424175; called by muse, mutect2, varscan2
- RELN | c.9491C>A p.S3164Y | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100634705; called by muse, mutect2, varscan2
- RIN2 | c.2368G>A p.A790T (on ENST00000255006 / NM_001242581.1; = p.A741T on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.981); catalogued as rs189523512; called by muse, mutect2, varscan2
- RPUSD2 | c.1550T>A p.F517Y | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100225272; called by muse, mutect2, varscan2
- SCN1A | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1266240114, COSV57684963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEZ6L | c.2741G>A p.R914H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs752023482, COSV50661498; called by muse, mutect2, varscan2
- SFMBT1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775415477, COSV56251755; called by muse, mutect2, varscan2
- SMU1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs79227130, COSV101238501; called by muse, mutect2, varscan2
- SMYD1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs370403665, COSV101352506; called by muse, mutect2, varscan2
- SNAP91 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs577667798, COSV99536374; called by muse, varscan2
- STAG3 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1408162370, COSV100426156; called by muse, mutect2, varscan2
- SYNE1 | c.14560G>T p.A4854S (on ENST00000367255 / NM_182961.4; = p.A4783S on NM_033071.3) | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV99576243; called by muse, mutect2, varscan2
- TAF1L | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99645314, COSV99645448; called by muse, mutect2, varscan2
- TMEM131L | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs142713810; called by muse, mutect2, varscan2
- TMEM132D | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.808); catalogued as rs1287424489, COSV70603146; called by muse, mutect2
- TMX3 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as rs1475140298, COSV55185248; called by muse, mutect2, varscan2
- TOMM70 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as rs144929730; called by muse, mutect2, varscan2
- TSHZ3 | c.2021del p.P674Rfs*22 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV53674233; called by mutect2, pindel, varscan2
- USP24 | c.3268G>A p.A1090T | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs928128284, COSV99599509; called by muse, mutect2, varscan2
- USP53 | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398931495, COSV99918009; called by muse, mutect2
- WNT16 | c.469G>A p.G157S (on ENST00000222462 / NM_057168.2; = p.G147S on NM_016087.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.145); catalogued as COSV55976356; called by muse, mutect2, varscan2
- ZNF100 | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 68/187 reads (36%) | catalogued as COSV59748413; called by muse, mutect2, varscan2
- ZXDA | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.473); catalogued as rs767523196, COSV62388872; called by muse, mutect2, varscan2
- ASIC2 | c.1261_1263del p.K421del | In Frame Del (DEL) | VAF 43/133 reads (32%) | called by pindel, varscan2
- OR5P2 | c.913dup p.I305Nfs*5 | Frame Shift Ins (INS) | VAF 79/260 reads (30%) | called by mutect2, pindel, varscan2
- R3HCC1L | c.1851del p.E618Rfs*66 (on ENST00000612478 / NM_001256619.2; = p.E604Rfs*66 on NM_014472.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 86/240 reads (36%) | called by mutect2, pindel, varscan2
- TGIF1 | c.9_11del p.P4del (on ENST00000330513 / NM_001374396.1; = p.P24del on NM_003244.4) | In Frame Del (DEL) | VAF 92/249 reads (37%) | called by mutect2, pindel*, varscan2*
- XKR3 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFP90 | c.376del p.Q126Sfs*2 | Frame Shift Del (DEL) | VAF 80/225 reads (36%) | called by mutect2, pindel, varscan2
- ABCD4 | c.759G>A p.L253= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100084521; called by muse, mutect2, varscan2
- CDX4 | c.72C>T p.D24= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as rs775744896, COSV65171484; called by muse, mutect2, varscan2
- CELSR2 | c.4143C>T p.R1381= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs767449979, COSV99604626; called by mutect2, varscan2
- CEP89 | c.2307C>T p.C769= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs201835752, COSV59865236; called by muse, mutect2
- DCST1 | c.225C>T p.Y75= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs770940125, COSV55052481; called by muse, mutect2, varscan2
- DDX43 | c.1665C>T p.D555= | Silent (SNP) | VAF 71/157 reads (45%) | catalogued as rs555241829, COSV100944054; called by muse, mutect2, varscan2
- DNAJA4 | c.1131C>T p.H377= (on ENST00000343789; = p.H406= on NM_018602.3) | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs370351978; called by muse, mutect2, varscan2
- FBN3 | c.1809G>A p.A603= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1316771496, COSV54478634; called by muse, mutect2, varscan2
- FOSB | c.678C>T p.Y226= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100798812; called by muse, mutect2, varscan2
- GABRG3 | c.846G>A p.T282= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs756924937, COSV100408290; called by muse, mutect2, varscan2
- GPNMB | c.1662G>A p.P554= (on ENST00000381990 / NM_001005340.2; = p.P542= on NM_002510.3) | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs745413407, COSV99326786; called by muse, mutect2, varscan2
- GPR32 | c.177G>A p.L59= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99567352; called by muse, mutect2, varscan2
- HERC2 | c.7122G>A p.P2374= | Silent (SNP) | VAF 41/288 reads (14%) | catalogued as rs529205569, COSV55350383, COSV99876398; called by muse, mutect2, varscan2
- KLHL9 | c.57T>C p.C19= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as COSV100757157; called by muse, mutect2, varscan2
- NFASC | c.2997C>T p.S999= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs114445942; called by mutect2, varscan2
- OR4Q3 | c.579C>A p.V193= | Silent (SNP) | VAF 72/175 reads (41%) | catalogued as COSV100057328; called by muse, mutect2, varscan2
- PCDHA12 | c.1767C>T p.H589= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV56516535; called by muse, mutect2, varscan2
- PCDHGB1 | c.1959C>T p.T653= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV53972818; called by muse, mutect2, varscan2
- POU4F2 | c.879G>A p.S293= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV99850790; called by muse, mutect2, varscan2
- PRXL2A | c.687A>G p.K229= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as COSV100939828; called by muse, mutect2, varscan2
- RBFOX1 | c.147G>A p.A49= | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as rs752770034, COSV60957261; called by muse, mutect2, varscan2
- RELN | c.4041C>T p.C1347= | Silent (SNP) | VAF 68/224 reads (30%) | catalogued as rs762723785, COSV58998855; ClinVar: likely benign; called by muse, mutect2, varscan2
- S1PR2 | c.90G>A p.T30= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs776010598, COSV100495361; called by muse, mutect2, varscan2
- SAMD9L | c.2350C>T p.L784= | Silent (SNP) | VAF 254/681 reads (37%) | catalogued as COSV100561090; called by muse, mutect2, varscan2
- SEMA6D | c.2430G>A p.P810= (on ENST00000316364 / NM_153618.2; = p.P748= on NM_020858.2) | Silent (SNP) | VAF 80/268 reads (30%) | catalogued as rs144939945; called by muse, mutect2, varscan2
- SNAP25 | c.255C>T p.C85= | Silent (SNP) | VAF 69/257 reads (27%) | called by muse, mutect2, varscan2
- SPTA1 | c.3846G>A p.K1282= | Silent (SNP) | VAF 144/215 reads (67%) | catalogued as rs773466647, COSV63752414; called by muse, mutect2, varscan2
- STARD4 | c.165C>T p.A55= | Silent (SNP) | VAF 53/183 reads (29%) | catalogued as COSV99685398; called by muse, mutect2, varscan2
- THRAP3 | c.1005G>A p.E335= | Silent (SNP) | VAF 47/89 reads (53%) | catalogued as COSV100663564; called by muse, mutect2, varscan2
- UBTD1 | c.471G>A p.T157= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs758894209, COSV53968633; called by muse, mutect2, varscan2
- ZNF563 | c.315C>T p.S105= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as rs771388021, COSV99536477, COSV99536764; called by muse, mutect2, varscan2
- C8orf31 | n.666C>A | RNA (SNP) | VAF 5/16 reads (31%) | catalogued as rs1293732222; called by muse, mutect2, varscan2
- DCHS2 | n.5015C>A | RNA (SNP) | VAF 66/165 reads (40%) | catalogued as COSV100602513; called by muse, mutect2, varscan2
- NRG1 | c.502+30931G>A | Intron (SNP) | VAF 30/96 reads (31%) | catalogued as rs750558927, COSV99827170, COSV99829337; called by muse, mutect2, varscan2
- SNORD115-38 | n.9G>T | RNA (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
